Somatic mutation profile of tumor specimen C3N-02240-03 (aliquot CPT0215210009) from CPTAC case C3N-02240, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 49.8 years (18,199 days).
Specimen C3N-02240-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bac7a25e-aa01-4980-8e71-392c47c11f9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02240-71 (Blood Derived Normal), aliquot CPT0215310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e67ddfe-ed5e-4660-8b17-00f1970ee736

The open-access MAF lists 67 somatic variants for this specimen: 53 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 9, Intron 4, Nonsense Mutation 2, Splice Region 2, RNA 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2313_2324dup p.Y772_A775dup | In Frame Ins (INS) | VAF 40/161 reads (25%) | hotspot (GDC flag); catalogued as rs397516975; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.96+1_96+3del p.X32_splice | Splice Site (DEL) | VAF 89/273 reads (33%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ATG2A | c.3002C>T p.P1001L | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs532103823; called by muse, mutect2, varscan2
- ATXN2L | c.2477C>T p.T826M | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as rs373039080; called by muse, mutect2
- CLVS1 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.267); catalogued as rs1361128567; called by muse, mutect2, varscan2
- DDX54 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs1160276047, COSV58373916; called by muse, mutect2
- EXOC3L2 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs139655836; called by muse, mutect2, varscan2
- F11 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.929); catalogued as rs201688862, CM083501, COSV53007113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRS2 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs762081662, COSV54726117; called by muse, mutect2, varscan2
- GGA1 | c.1332-7G>A | Splice Region (SNP) | VAF 11/151 reads (7%) | catalogued as rs576614066; called by muse, mutect2
- GRK1 | c.1155G>A p.M385I | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as rs1176288575; called by muse, mutect2
- KAT8 | c.997A>G p.I333V | Missense Mutation (SNP) | VAF 15/343 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1345968617, COSV54896112; called by muse, mutect2
- KIAA2026 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374017073; called by muse, mutect2, varscan2
- KMT2E | c.4195C>T p.L1399F | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as rs747079148; called by muse, mutect2, varscan2
- PCNX3 | c.2644C>T p.P882S | Missense Mutation (SNP) | VAF 42/484 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.283); catalogued as rs772904375; called by muse, mutect2
- PHLDB1 | c.3554G>A p.R1185Q | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1194257386; called by muse, mutect2, varscan2
- PPP1R9B | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 82/349 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs920945780; called by muse, mutect2, varscan2
- RBM12 | c.244A>G p.M82V | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.914); catalogued as rs1568939650; called by muse, mutect2, varscan2
- RPS8 | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1293497325; called by muse, mutect2, varscan2
- SHKBP1 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as rs775683649, COSV99190861; called by muse, mutect2, varscan2
- SPECC1 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs781356902; called by muse, mutect2, varscan2
- SULF1 | c.489C>G p.I163M | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs199957740; called by muse, mutect2
- TMEM266 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs1189010322, COSV101189606; called by muse, mutect2
- VCX | c.287G>A p.S96N | Missense Mutation (SNP) | VAF 52/514 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.087); catalogued as rs374421861; called by muse, varscan2
- ADAM19 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AL121899.2 | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2
- AMHR2 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2
- ARID2 | c.3804C>A p.N1268K | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- CDKN2D | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 105/402 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CLDN17 | c.566A>T p.N189I | Missense Mutation (SNP) | VAF 42/367 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CPA1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2
- CPXM2 | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 54/385 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DACT2 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EPHX3 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 69/228 reads (30%) | called by muse, mutect2, varscan2
- GRK1 | c.1156A>T p.I386F | Missense Mutation (SNP) | VAF 21/308 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2
- GTPBP8 | c.508T>A p.F170I | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- HSP90AB1 | c.921C>G p.S307R | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- JARID2 | c.3499C>A p.R1167S | Missense Mutation (SNP) | VAF 61/295 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KPNA2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 60/152 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- MAGEL2 | c.151T>G p.L51V | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- NUP88 | c.1836-4T>A | Splice Region (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- PGBD1 | c.1601T>C p.L534P | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- PPP1R26 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- QPCT | c.914A>T p.D305V | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- STS | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D4 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 18/455 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- TENM4 | c.4796A>G p.Q1599R | Missense Mutation (SNP) | VAF 35/350 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TFAP2D | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 205/386 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by mutect2, varscan2
- TLR8 | c.2277G>T p.K759N (on ENST00000218032 / NM_138636.5; = p.K777N on NM_016610.4) | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TMEM94 | c.2090C>G p.T697R | Missense Mutation (SNP) | VAF 79/281 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- TMTC1 | c.1031C>G p.P344R (on ENST00000539277 / NM_001193451.2; = p.P236R on NM_175861.3) | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TOGARAM2 | c.1342T>A p.F448I | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- XYLT1 | c.2462G>A p.W821* | Nonsense Mutation (SNP) | VAF 50/245 reads (20%) | called by muse, mutect2, varscan2
- ANKRD30B | c.573A>G p.L191= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1394110353; called by muse, mutect2, varscan2
- ATXN2L | c.1521A>G p.K507= | Silent (SNP) | VAF 62/242 reads (26%) | called by muse, varscan2
- DNAH5 | c.4731T>C p.S1577= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as COSV54222510; called by muse, mutect2, varscan2
- LAMA1 | c.3666G>A p.P1222= | Silent (SNP) | VAF 107/394 reads (27%) | catalogued as rs752558115, COSV67544161; called by muse, mutect2, varscan2
- OR5AP2 | c.201C>T p.F67= | Silent (SNP) | VAF 19/121 reads (16%) | called by muse, mutect2, varscan2
- PRPH | c.801C>T p.D267= | Silent (SNP) | VAF 43/335 reads (13%) | called by muse, mutect2, varscan2
- RASSF7 | c.978G>A p.E326= | Silent (SNP) | VAF 12/226 reads (5%) | catalogued as rs1186192256; called by muse, mutect2
- SNX20 | c.597C>T p.G199= | Silent (SNP) | VAF 45/153 reads (29%) | called by muse, mutect2, varscan2
- SUV39H2 | c.303A>G p.L101= (on ENST00000354919 / NM_001193424.2; = p.L41= on NM_024670.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV57952419; called by muse, mutect2
- CMPK1 | c.172-10123C>T | Intron (SNP) | VAF 17/135 reads (13%) | catalogued as rs1470985204; called by muse, mutect2, varscan2
- MDM1 | c.134-441C>T | Intron (SNP) | VAF 45/157 reads (29%) | called by muse, mutect2, varscan2
- NBPF7 | n.588G>A | RNA (SNP) | VAF 24/269 reads (9%) | called by muse, mutect2
- SLC11A2 | c.1508+50G>A | Intron (SNP) | VAF 58/151 reads (38%) | catalogued as rs185973429; called by muse, mutect2, varscan2
- SPEG | c.2882-1150C>T | Intron (SNP) | VAF 20/199 reads (10%) | catalogued as rs1264077593; called by muse, mutect2, varscan2
